Gene-level copy-number profile of tumor specimen C3N-01489-02 from CPTAC case C3N-01489, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G3; Age at diagnosis: 65.2 years (23,810 days).
Specimen C3N-01489-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 69d16b60-cddf-4246-9832-2ca8276e7af8.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-01489-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,706 have no estimate.
https://portal.gdc.cancer.gov/files/12d7f943-3c0e-49a0-bfa3-1c13af7a7cbe

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 231; copy number 1: 17,250; copy number 2: 37,023; copy number 3: 3,682; copy number 4: 512; copy number 5: 98; copy number 6: 36; copy number 7: 11; copy number 8: 2; copy number 9: 46; copy number 11: 13; copy number 16: 13.

Homozygous deletions (total copy number 0; autosomes only): 16 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:29,906,543–29,934,286, 5 genes: DDX39BP1, MCCD1P1, HCG4B, HLA-K, HLA-U.
- chr6:31,399,784–31,478,936, 6 genes (within-gene range 0–1): MICA, AL645933.3, Y_RNA, LINC01149, AL645933.1, HCP5.
- chr22:18,605,355–18,625,289, 5 genes: AC023490.1, RN7SKP131, RIMBP3, Metazoa_SRP, SUSD2P2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 217 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:195,836,193–195,860,404, 1 gene, copy number 5 (within-gene range 3–5): LINC01983.
- chr3:195,863,364–198,123,232, 90 genes, copy number 5 (broad region; genes not listed).
- chr4:45,995,119–46,531,342, 6 genes, copy number 5: RN7SKP199, GABRG1, AC104072.1, GABRA2, AC095060.1, RNU6-412P.
- chr4:48,483,343–48,494,389, 2 genes, copy number 8: SLC10A4, ZAR1.
- chr4:51,843,000–54,295,272, 36 genes, copy number 6–7 (within-gene range 4–7): DCUN1D4, DUTP7, AC027271.1, AC104784.1, LRRC66, SGCB, LINC02480, SPATA18, AC097522.2, AC097522.1, RNU6-1252P, USP46, USP46-DT, AC104066.3, DANCR, LINC01618, MIR4449, AC104066.4, SNORA26, AC104066.2, ERVMER34-1, AC104066.1, Y_RNA, RASL11B, SCFD2, AC023154.1, RNU6-310P, FIP1L1, AC058822.1, LNX1, LNX1-AS1, AC095040.1, LNX1-AS2, AC124017.1, AC105384.1, AC105384.2.
- chr4:54,065,239–54,078,454, 1 gene, copy number 7 (within-gene range 4–7): AC110792.4.
- chr4:54,221,126–58,103,434, 79 genes, copy number 6–16 (broad region; genes not listed).
- chr4:58,524,515–58,565,212, 2 genes, copy number 6: LINC02494, AC019133.1.

Autosomal genes at a single copy (total copy number 1): 14,615. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
